Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADB, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADB-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Laparoscopic wedge resection

Organ: Liver (9.0 x 5.0 x 3.5 cm, 49.0 gm)

Lesion: Hepatic mass

Size: 1.5 x 1.2 x 1.0 cm

Cut surface: Encapsulated, pale tan, solid and lobulated mass

No necrosis and hemorrhage

Gross type: Multinodular confluent

Extent: Abuts but confined to the capsule

Resection margin: Not involved, grossly (safety margin: 2.0 cm)

Remaining parenchyme: Unremarkable, grossly

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, mass of liver x 4

RM, mass with resection margin x 1

L, nontumorous liver parenchyme x 1

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

The worst differentiation IV

The major differentiation III

Histologic type: Nesting

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Yes

Capsular infiltration: Focal

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Vascular invasion: No

Bile duct invasion: No

Remaining liver parenchyme: Cirrhosis

IMMUNOHISTOCHEMISTRY: CD34 (-)

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver NOS
C22.0

QAD 5/19/14

[page 2 of 2]
NOT reported. Gross:

Liver, resection, hepatocellular carcinoma
T56000, P17, M81703

DIAGNOSIS:

Liver, segment 2-3, left, laparoscopic wedge resection:
Hepatocellular carcinoma

NOTE:

Suggestion :

hw 1/13/14

Source: NCI Genomic Data Commons file 4e6221a0-1eba-4e1d-a906-d21d37509c0f (TCGA-DD-AADB.3963D999-C204-45C2-8515-B922BEBA7C9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).